MMRF case MMRF_1593 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/38283de8-d70b-49ef-89cd-83d84794de65

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.2 years (24,923 days); ISS stage: II; Days to last known disease status: 1,213 days (3.3 years); Days to last follow up: 1,213 days (3.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 73 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 105 days; Days to treatment end: 133 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 105 days; Days to treatment end: 189 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 133 days; Days to treatment end: 189 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 133 days; Days to treatment end: 217 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 216 days; Days to treatment end: 216 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 218 days; Days to treatment end: 218 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 312 days; Days to treatment end: 343 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 343 days; Days to treatment end: 492 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 492 days (1.3 years); Days to treatment end: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 606 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 305 mg/dL; Immunoglobulin G 6.76 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.497 g/L; Beta 2 Microglobulin 4.9 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 8.8 ×10⁹/L; Absolute Neutrophil 6.7 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 333 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 6.99 mmol/L; C-Reactive Protein 0.059 mg/dL.
- Day 95 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.315 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.99 mg/dL; Immunoglobulin G 4.54 g/L; Immunoglobulin A 0.323 g/L; Immunoglobulin M 0.364 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 20.1 ×10⁹/L; Absolute Neutrophil 17.7 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.2 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.
- Day 193 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 4.21 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.48 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Albumin 46 g/L; Total Protein 6.3 g/dL; Glucose 6.55 mmol/L.
- Day 277 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.725 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.72 mmol/L.
- Day 492 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.833 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 6.99 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 4.46 mmol/L.
- Day 604 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 5.26 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 758 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 6.99 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.28 mmol/L.
- Day 940 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 7.07 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.23 mmol/L.
- Day 1,122 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.55 mg/dL; Immunoglobulin G 7.15 g/L; Immunoglobulin A 1.54 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.44 mmol/L.
- Day 1,213 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Immunoglobulin G 7.97 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 9.55 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.06 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.29 mmol/L.

Other clinical attributes
- Day -3: Weight: 102 kg; Height: 188 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1593_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1593_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
